Somatic mutation profile of tumor specimen MMRF_2200_1_BM_CD138pos (aliquot MMRF_2200_1_BM_CD138pos_T1_KHS5U_L08840) from MMRF case MMRF_2200, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,385 days).
Specimen MMRF_2200_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d218558-76ec-4bc6-a589-cf5a57efb28c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2200_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2200_1_PB_WBC_C3_KHS5U_L08796; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7f9d201-f34e-4840-bdb8-e6269dbfbb32

The open-access MAF lists 190 somatic variants for this specimen: 73 protein-altering or splice-affecting, 19 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 52, Intron 29, Silent 19, 5'UTR 6, 3'Flank 5, Nonsense Mutation 4, Frame Shift Del 3, RNA 3, 5'Flank 3, Splice Site 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACOT4 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs768588320; called by muse, mutect2, varscan2
- BHMT | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV104387249, COSV57156206; called by muse, mutect2, varscan2
- BRINP3 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs142073525, COSV100818504; called by muse, mutect2, varscan2
- C12orf56 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV61484928; called by muse, mutect2, varscan2
- CCN4 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs140971140; called by muse, mutect2, varscan2
- CDH22 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs752436980; called by muse, mutect2, varscan2
- DCC | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279908257; called by muse, mutect2, varscan2
- DUS3L | c.625G>A p.G209S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1295086525, COSV100288203; called by muse, mutect2, varscan2
- GABPB2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as rs760498129; called by muse, mutect2, varscan2
- GIT1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV56402317; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- IGHV2-70 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs544365977; called by muse, varscan2
- IGLL5 | c.206+2T>G p.X69_splice | Splice Site (SNP) | VAF 5/9 reads (56%) | catalogued as rs561122720, COSV73250168, COSV73251186; called by muse, varscan2
- MATK | c.1132C>T p.R378W (on ENST00000310132 / NM_139355.3; = p.R379W on NM_002378.4) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs767974303, COSV59553226; called by muse, mutect2, varscan2
- MMP2 | c.285G>C p.E95D | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54603656; called by muse, mutect2
- MRGPRE | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.916); catalogued as rs1402939547; called by muse, mutect2, varscan2
- MTHFR | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745779146; called by muse, mutect2, varscan2
- NCAN | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs756245904; called by muse, mutect2, varscan2
- RBMXL3 | c.1279C>T p.R427* | Nonsense Mutation (SNP) | VAF 45/56 reads (80%) | catalogued as rs1346438615, COSV57760435; called by muse, mutect2, varscan2
- SH2D5 | c.659C>T p.A220V (on ENST00000444387 / NM_001103161.2; = p.A136V on NM_001103160.2) | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66706322; called by muse, mutect2
- STK33 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as rs199852553; called by muse, mutect2, varscan2
- TGIF1 | c.131C>T p.S44L (on ENST00000330513 / NM_001374396.1; = p.S64L on NM_003244.4) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57908885; called by muse, mutect2, varscan2
- TMPRSS6 | c.1698C>A p.S566R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1198417521; called by muse, mutect2, varscan2
- TRIM68 | c.1049G>T p.S350I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs1355206580; called by muse, mutect2
- TSSK4 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565333393; called by muse, mutect2, varscan2
- UNC80 | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as rs1035839091; called by muse, mutect2, varscan2
- ZBTB38 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58543717; called by muse, mutect2, varscan2
- ZNF804A | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1157606887; called by muse, mutect2, varscan2
- BAZ1A | c.2300G>C p.R767T | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEGAIN | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CD40 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by mutect2, varscan2
- CRYBG3 | c.3085del p.V1031Yfs*5 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | called by mutect2, pindel, varscan2
- DIAPH1 | c.294G>C p.Q98H | Missense Mutation (SNP) | VAF 71/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DISP1 | c.3416C>G p.T1139S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMXL2 | c.4574G>T p.G1525V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DRG2 | c.465G>A p.Q155= | Splice Region (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.4274_4283del p.A1425Dfs*11 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- FMNL2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.171); called by muse, mutect2
- FOXO1 | c.391C>G p.L131V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- FRMPD1 | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN2 | c.11875G>C p.V3959L | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGLV3-25 | c.334A>T p.S112C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); called by muse, varscan2
- ITGAV | c.2501A>G p.N834S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- KIF9 | c.810A>C p.K270N | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KLHL13 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KPRP | c.577C>G p.P193A | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, varscan2
- LHX9 | c.822C>G p.F274L | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MESP2 | c.558_605del p.Q190_G205del | In Frame Del (DEL) | VAF 11/22 reads (50%) | called by mutect2, varscan2*
- NDUFS6 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- OR56A3 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- OR6Y1 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOF | c.5681C>A p.A1894D (on ENST00000272371 / NM_194248.3; = p.A1127D on NM_004802.4) | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- P3H4 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PATZ1 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PELO | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PRKDC | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SETD2 | c.6212_6216del p.N2071Rfs*17 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- SLC15A4 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SPAG17 | c.2625G>T p.E875D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SRA1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SULF2 | c.413C>G p.T138R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUPT20H | c.293-1G>A p.X98_splice (on ENST00000350612 / NM_001014286.3; = p.X99_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TDRD6 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TNRC6B | c.2374G>C p.A792P | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- TRPM6 | c.2945T>A p.I982N | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- WDR81 | c.4636G>T p.G1546C (on ENST00000409644 / NM_001163809.2; = p.G495C on NM_152348.4) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF382 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZNF45 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ZNF470 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ZNF703 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF786 | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARFRP1 | c.369G>A p.A123= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs1224824107, COSV53927624; called by muse, mutect2, varscan2
- BTN1A1 | c.1008G>A p.E336= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1165762504, COSV55069448, COSV99764432; called by muse, mutect2, varscan2
- GABBR2 | c.1347G>A p.L449= | Silent (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- GCC1 | c.1104T>C p.N368= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- GLYATL1 | c.864G>A p.E288= (on ENST00000317391 / NM_001354699.1; = p.E319= on NM_080661.4) | Silent (SNP) | VAF 45/123 reads (37%) | called by muse, mutect2, varscan2
- GPR119 | c.345G>A p.K115= | Silent (SNP) | VAF 70/83 reads (84%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.333C>T p.S111= | Silent (SNP) | VAF 42/180 reads (23%) | catalogued as rs769962131; called by muse, varscan2
- KCNMA1 | c.348C>G p.T116= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs200178895; ClinVar: likely benign; called by mutect2, varscan2
- LMF1 | c.1371G>A p.P457= | Silent (SNP) | VAF 61/139 reads (44%) | catalogued as rs747350625, COSV51893684, COSV99235879; called by muse, mutect2, varscan2
- LRCH3 | c.720C>T p.L240= | Silent (SNP) | VAF 51/137 reads (37%) | called by muse, mutect2, varscan2
- MAPT | c.1155C>T p.N385= (on ENST00000262410 / NM_001377265.1; = p.N310= on NM_016835.4) | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as rs745350248; ClinVar: likely benign; called by muse, mutect2, varscan2
- PEX11B | c.15C>T p.V5= | Silent (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- PIGM | c.432T>A p.G144= | Silent (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- PURA | c.144C>G p.G48= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs1357882015, COSV58761907; called by muse, mutect2
- RAPGEF3 | c.2589C>G p.L863= (on ENST00000389212; = p.L821= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs983476994, COSV50201965, COSV99406705; called by muse, mutect2, varscan2
- SLC8A2 | c.1407C>T p.D469= | Silent (SNP) | VAF 54/207 reads (26%) | catalogued as COSV52643708, COSV99369784; called by muse, mutect2, varscan2
- STRN4 | c.576C>G p.L192= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- TBXT | c.1122G>A p.Q374= | Silent (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- UNC79 | c.957T>G p.A319= (on ENST00000393151 / NM_001346218.2; = p.A142= on NM_020818.5) | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, varscan2
- AC011525.1 | n.1112T>G | RNA (SNP) | VAF 22/55 reads (40%) | catalogued as rs925112235; called by muse, mutect2, varscan2
- ADAM17 | c.844-436C>A | Intron (SNP) | VAF 20/49 reads (41%) | called by muse, varscan2
- AL161729.4 | chr9:95516805 T>A | 3'Flank (SNP) | VAF 64/121 reads (53%) | called by muse, mutect2, varscan2
- ANKS3 | c.170+35G>A | Intron (SNP) | VAF 27/52 reads (52%) | called by muse, varscan2
- APP | c.1687+8880del | Intron (DEL) | VAF 15/47 reads (32%) | catalogued as rs1569090196; called by mutect2, pindel, varscan2
- ARHGEF28 | c.4948+67C>G | Intron (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- ASB4 | c.*2060C>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- ATP5MC2 | c.-32+56G>T | Intron (SNP) | VAF 51/134 reads (38%) | catalogued as rs35269323, COSV58602156, COSV58602692; called by muse, varscan2
- ATP8B4 | c.435+1422A>T | Intron (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- C12orf4 | c.1238-2121G>A | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2
- CACUL1 | c.-37G>T | 5'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- CCDC141 | c.4325+120A>G | Intron (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- CEBPA | c.*477C>T | 3'UTR (SNP) | VAF 14/26 reads (54%) | catalogued as rs1029623078; called by muse, mutect2, varscan2
- CENPS-CORT | c.-253G>C | 5'UTR (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- CFHR4 | c.1355-78A>G | Intron (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- CLCN5 | chrX:50095069 G>A | 3'Flank (SNP) | VAF 34/41 reads (83%) | catalogued as rs1374881939; called by muse, mutect2, varscan2
- CSRNP3 | c.*4292T>C | 3'UTR (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- CYP2E1 | chr10:133527358 A>G | 5'Flank (SNP) | VAF 48/71 reads (68%) | called by mutect2, varscan2
- CYRIA | c.*2410G>A | 3'UTR (SNP) | VAF 21/67 reads (31%) | catalogued as rs1262674952; called by muse, mutect2, varscan2
- DCC | c.*2908G>A | 3'UTR (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- DGKB | c.*458C>T | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*1403G>A | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- DSCAM | c.*357G>A | 3'UTR (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- DZIP1 | c.*195G>A | 3'UTR (SNP) | VAF 32/99 reads (32%) | catalogued as rs1037890561, COSV54826755; called by muse, mutect2, varscan2
- ENSA | c.350+1175C>A | Intron (SNP) | VAF 110/318 reads (35%) | called by muse, mutect2, varscan2
- ERGIC2 | c.*3532T>C | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- EYA4 | chr6:133531865 G>A | 3'Flank (SNP) | VAF 27/33 reads (82%) | called by muse, mutect2, varscan2
- FAM102A | c.*2088C>T | 3'UTR (SNP) | VAF 68/128 reads (53%) | called by muse, mutect2, varscan2
- FAM24B | c.*72G>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- FBP2 | chr9:94593911 C>G | 5'Flank (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- FLI1 | c.*698T>G | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- GPR83 | c.*2487A>G | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- GSTA1 | c.*67T>C | 3'UTR (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
- HEYL | c.*158C>G | 3'UTR (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- HINT2 | c.400+40C>A | Intron (SNP) | VAF 58/167 reads (35%) | catalogued as COSV52414182; called by muse, mutect2, varscan2
- HNRNPH1 | c.254-17C>G | Intron (SNP) | VAF 20/58 reads (34%) | catalogued as rs372649727; called by muse, mutect2, varscan2
- HOXB8 | c.*187G>T | 3'UTR (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- HUNK | c.*3970G>T | 3'UTR (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- IPO9 | c.*3919A>C | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- IQSEC3 | c.*2555C>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | catalogued as rs1223504711; called by muse, varscan2
- IRF4 | c.*3034T>G | 3'UTR (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2
- ITGB6 | c.*843T>A | 3'UTR (SNP) | VAF 17/65 reads (26%) | catalogued as rs533686326; called by muse, varscan2
- KBTBD11 | c.*3276C>T | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- KDM7A | c.*811A>G | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- KIAA1614 | c.*4473G>A | 3'UTR (SNP) | VAF 5/33 reads (15%) | catalogued as rs962538491; called by muse, mutect2
- LRAT | c.*3458A>T | 3'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- LRRC57 | c.223+11C>T | Intron (SNP) | VAF 29/64 reads (45%) | catalogued as rs746555142; called by muse, mutect2, varscan2
- LYRM2 | c.*993G>A | 3'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- MAP3K1 | c.*314C>A | 3'UTR (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- MAP3K12 | c.723-28G>C | Intron (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- MAP3K13 | c.*3540A>G | 3'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- MED15 | c.*817C>G | 3'UTR (SNP) | VAF 50/104 reads (48%) | called by muse, mutect2, varscan2
- MFSD8 | c.999-14C>A | Intron (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- MOGAT2 | c.*1578G>A | 3'UTR (SNP) | VAF 42/83 reads (51%) | catalogued as rs944042566; called by muse, mutect2, varscan2
- NDUFS1 | c.*293C>T | 3'UTR (SNP) | VAF 13/32 reads (41%) | catalogued as rs1272487888; called by muse, mutect2
- NUP54 | c.907+16C>T | Intron (SNP) | VAF 31/64 reads (48%) | catalogued as rs776354282; called by muse, mutect2, varscan2
- ODF2 | c.-170C>A | 5'UTR (SNP) | VAF 160/653 reads (25%) | catalogued as rs759921308; called by muse, mutect2, varscan2
- PAPOLB | c.*1008C>G | 3'UTR (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- PAX6 | c.10+1770A>T | Intron (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- PDCD5 | c.258+44A>G | Intron (SNP) | VAF 65/162 reads (40%) | catalogued as rs752098381; called by muse, mutect2, varscan2
- PDCD6IPP2 | n.149G>C | RNA (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- PHTF1 | c.1890+187C>G | Intron (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- POLR2C | c.609-62A>C | Intron (SNP) | VAF 22/33 reads (67%) | called by muse, mutect2, varscan2
- POLR2C | c.683+25A>G | Intron (SNP) | VAF 26/34 reads (76%) | called by muse, mutect2
- PTPN20 | chr10:47002243 G>A | 3'Flank (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- PYCR3 | c.*47C>T | 3'UTR (SNP) | VAF 9/27 reads (33%) | catalogued as COSV55309759; called by muse, mutect2, varscan2
- RASL10B | c.*2034G>A | 3'UTR (SNP) | VAF 99/232 reads (43%) | catalogued as rs1007889987; called by muse, mutect2, varscan2
- RNF150 | c.*2563C>T | 3'UTR (SNP) | VAF 14/19 reads (74%) | called by muse, mutect2, varscan2
- RPN2 | c.13+58C>T | Intron (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- RSPO4 | c.*293C>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- RUNX1 | c.-668T>A | 5'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- RXYLT1 | c.-7G>A | 5'UTR (SNP) | VAF 98/238 reads (41%) | catalogued as rs548122095; called by muse, mutect2, varscan2
- SESTD1 | c.*4036G>T | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SLC12A1 | c.628+2094C>T | Intron (SNP) | VAF 4/90 reads (4%) | catalogued as rs1008523156; called by muse, mutect2
- SLC25A15 | c.*238T>C | 3'UTR (SNP) | VAF 68/194 reads (35%) | catalogued as rs1300794336; called by muse, mutect2, varscan2
- SLC35G3 | c.*437G>T | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- SLFN13 | c.*3290G>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3650C>T | RNA (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- SPATA6 | c.*2020C>T | 3'UTR (SNP) | VAF 17/23 reads (74%) | called by muse, mutect2, varscan2
- SPEN | c.*231C>A | 3'UTR (SNP) | VAF 20/36 reads (56%) | called by muse, mutect2, varscan2
- SPTBN1 | c.6420+1153G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- STIMATE | c.*2488_*2507del | 3'UTR (DEL) | VAF 6/72 reads (8%) | catalogued as COSV104422124; called by mutect2, varscan2
- TACC2 | c.5835-2283G>T | Intron (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- TAS2R3 | c.*6C>T | 3'UTR (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2618+635C>G | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- TM9SF3 | c.*3840A>C | 3'UTR (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- TMEM132D | c.-332G>A | 5'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- TMEM213 | c.*2677A>G | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- TMEM33 | c.*1707G>C | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- TMEM71 | c.752+92T>G | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115411829 A>G | 3'Flank (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.*1545C>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- UBE3C | c.*107A>T | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- UTP25 | c.2027+313G>T | Intron (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- YPEL4 | c.-184-117dup | Intron (INS) | VAF 25/175 reads (14%) | catalogued as rs551973712; called by mutect2, varscan2
- Y_RNA | chr12:54102373 C>T | 5'Flank (SNP) | VAF 57/136 reads (42%) | called by muse, mutect2, varscan2
- ZNF260 | c.*134_*141del | 3'UTR (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- ZNF354C | c.*2060G>T | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
